Surgical pathology report (de-identified scan), TCGA case TCGA-G3-AAV0, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-AAV0-01A (Primary Tumor).

[page 1 of 2]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
Copied To		Location	

Report Patient
Demographics (for
verification purposes) Date of Birth:
Sex: M

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist
Specimen Description
Liver segments 6 and 7 @
Clinical Information
Hepatocellular cancer

ICD-O-3
Carcinoma, hepatocellular NOS 8170/3
Site: Liver (22.0)
7/5/20/14

Diagnosis

Liver (Segment 6 and 7), Resection:

- Moderately differentiated hepatocellular carcinoma, 5.5 cm in greatest dimension, tumor confined within liver capsule, resection margin uninvolved.
- Iron overload (2+)

Reported by:

Electronically signed by: .

Verified:

Synopsis Report

Specimen:

Liver

PROCEDURE:

Partial hepatectomy

*Minor hepatectomy (less than 3 segments)

TUMOR SIZE:

Greatest dimension: 5.5 cm

*Additional dimensions: 5 x 5 cm

TUMOR FOCALITY:

Solitary (specify location): segments 6 and 7

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GII: Moderately differentiated

TUMOR EXTENSION (select all that apply):

Tumor confined to liver

PRIMARY TUMOR (pT):

pT1: Solitary tumor with no vascular invasion

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

[page 2 of 2]
Parenchymal margin uninvolved
*VENOUS (LARGE VESSEL) INVASION (V):
*Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

*None identified

Gross Description

Received is a single specimen container. The acquisition and specimen container are labelled with the patient's name, The cassette and identifiers are labelled with the Surgical Number

The specimen is received fresh and is subsequently placed into formalin. The container is designated liver segment 6 and 7. The specimen consists of a wedge-shaped piece of liver which measures 12.5 x 7.5 x 5.5 cm. The capsule has a nodular appearance and shows peritoneal adhesions. The resection margin is painted black. The specimen is serially sectioned. The liver parenchyma underneath the nodular adhesion shows a circumscribed yellow tan single tumor which measures 5.5 x 5 x 5 cm. Sections:

A1. representative section of grossly normal liver parenchyma

A2-4. tumor with overlying capsule

A5-7. tumor

A8.

A9. tumor and closest resection margin

The closest margin is 1 cm from the tumor.

Microscopic Description

Sections of the grossly described tumor show moderately differentiated hepatocellular carcinoma which is confined within the liver capsule. The tumor shows clear cell change in many of the sections. Intracellular and canalicular bile pigment is noted in the neoplastic tissue. The resection margin is uninvolved. The surrounding liver parenchyma has a normal architecture and shows no significant histologic abnormalities. Special stain for iron shows iron overload (2+) and special stain for alpha-antitrypsin globule is negative.

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 7d14e497-51ba-4ded-ae0c-dcefb4a9d80f (TCGA-G3-AAV0.07528302-2925-4767-A47C-FE4EBA621202.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).